Somatic mutation profile of tumor specimen 0DX2CY from CCDI case PBCHUV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 5.7 years (2,067 days).
Specimen 0DX2CY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e038f91-327b-4cbc-a501-1b5efeafbb58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX2CB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2623e47-af95-4dd9-99ab-6376f9f450d6

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH3 | c.692T>C p.F231S | Missense Mutation (SNP) | VAF 24/926 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV56870656; called by muse, mutect2
- NRXN3 | c.3080G>A p.R1027H (on ENST00000335750 / NM_001330195.2; = p.R654H on NM_004796.6) | Missense Mutation (SNP) | VAF 44/988 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368490229; called by muse, mutect2
- DNPH1 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RSAD1 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 79/387 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SON | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 98/653 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SRCAP | c.4648G>C p.V1550L | Missense Mutation (SNP) | VAF 80/497 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.219); called by muse, mutect2, varscan2
